Somatic mutation profile of tumor specimen TCGA-EA-A78R-01A (aliquot TCGA-EA-A78R-01A-11D-A32I-09) from TCGA case TCGA-EA-A78R, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 54.6 years (19,942 days).
Specimen TCGA-EA-A78R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f85becd-4d2a-40ac-9180-aeaabf8831c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A78R-10A (Blood Derived Normal), aliquot TCGA-EA-A78R-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/266c25cb-e84a-4b5a-8275-7305e7a206be

The open-access MAF lists 63 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 40, Silent 17, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGFG2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53546458; called by muse, mutect2, varscan2
- AKR1C1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV66499627; called by muse, mutect2, varscan2
- AQR | c.3425G>A p.S1142N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV50044040; called by muse, mutect2, varscan2
- AREL1 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770551853, COSV62667421; called by muse, mutect2, varscan2
- BCAN | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs1407227763, COSV61258487; called by muse, mutect2, varscan2
- BUD13 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV52769836; called by muse, mutect2, varscan2
- CCDC40 | c.3113C>T p.S1038L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.645); catalogued as rs553780409, COSV56410377; called by muse, mutect2, varscan2
- CDK3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100043918; called by muse, mutect2, varscan2
- DNAH12 | c.890C>G p.S297* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV60858121; called by muse, mutect2, varscan2
- DNAJC27 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53096156; called by muse, mutect2, varscan2
- DPEP2 | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV52055318; called by muse, mutect2, varscan2
- FAM111A | c.1172T>C p.V391A | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV64655671; called by muse, mutect2, varscan2
- FAM126B | c.1566C>G p.F522L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.931); catalogued as COSV53774198; called by muse, mutect2, varscan2
- FBXO47 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as COSV65242406; called by muse, mutect2, varscan2
- GUCY2F | c.1179G>C p.L393F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV54300487, COSV54306266; called by muse, mutect2, varscan2
- IL4R | c.207C>T p.S69= | Splice Region (SNP) | VAF 14/59 reads (24%) | catalogued as rs575619134, COSV50157575; called by muse, mutect2, varscan2
- INTS3 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV59680298; called by muse, mutect2, varscan2
- KIAA0319 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs150777675; called by muse, mutect2, varscan2
- LAMA5 | c.10118G>A p.R3373Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs1472165176, COSV53367260; called by muse, mutect2, varscan2
- MAT1A | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372852106, CM036002, COSV64746591; called by muse, mutect2, varscan2
- MCFD2 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359783243, COSV60178281; called by muse, mutect2, varscan2
- NEMF | c.2021G>A p.R674K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV53593883; called by muse, mutect2, varscan2
- NRAP | c.2392T>G p.F798V (on ENST00000359988 / NM_001322945.2; = p.F763V on NM_006175.4) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV63492843; called by muse, mutect2, varscan2
- OR7G1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.06); catalogued as COSV53318442; called by muse, mutect2, varscan2
- PGR | c.2529G>C p.E843D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV54807458; called by muse, mutect2, varscan2
- PIP5K1C | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV58954645; called by muse, mutect2, varscan2
- PRPF3 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.099); catalogued as COSV61395768; called by muse, mutect2, varscan2
- PRR12 | c.1259C>G p.S420* (on ENST00000615927; = p.S1241* on NM_020719.3) | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV69819195; called by muse, mutect2, varscan2
- RABEPK | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV52337363; called by muse, mutect2, varscan2
- SEPSECS | c.1385G>C p.R462T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1278481233, COSV57205595, COSV57206847; called by muse, mutect2, varscan2
- SLCO4A1 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV53892706; called by muse, mutect2, varscan2
- SNW1 | c.1070A>T p.H357L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV55055732; called by muse, mutect2, varscan2
- SPIN2B | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV52069124; called by muse, mutect2, varscan2
- SZT2 | c.4255G>A p.D1419N (on ENST00000634258 / NM_001365999.1; = p.D1362N on NM_015284.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.602); catalogued as COSV65172498; called by muse, mutect2, varscan2
- TET1 | c.2671G>T p.V891L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV65387587; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4681G>A p.E1561K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV64101996; called by muse, mutect2, varscan2
- TPRN | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV58808541; called by muse, mutect2, varscan2
- TTN | c.70651G>A p.E23551K (on ENST00000591111; = p.E16127K on NM_003319.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | PolyPhen probably damaging (0.994); catalogued as COSV59885615, COSV60231755; called by muse, mutect2
- UBR4 | c.13844G>A p.G4615D | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV64395555; called by muse, mutect2, varscan2
- ULK4 | c.3253C>G p.L1085V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV57216998; called by muse, mutect2, varscan2
- VPS13A | c.2978C>T p.S993F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759878444, COSV62435055; called by muse, mutect2, varscan2
- WDR81 | c.4721C>T p.S1574F (on ENST00000409644 / NM_001163809.2; = p.S523F on NM_152348.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV58486440; called by muse, mutect2, varscan2
- ALYREF | c.626G>C p.R209T | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2
- IDO1 | c.180del p.K61Sfs*2 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by pindel, varscan2
- PIK3R1 | c.1340_1345del p.K447_L449delinsI (on ENST00000521381 / NM_181523.3; = p.K177_L179delinsI on NM_181504.4) | In Frame Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- RB1 | c.1450_1451del p.M484Vfs*8 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by pindel, varscan2
- ABCF2 | c.885C>T p.I295= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV55185252; called by muse, mutect2, varscan2
- ADPRH | c.213G>T p.G71= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV63695511; called by muse, mutect2, varscan2
- ARHGAP29 | c.2055T>C p.P685= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs1173263446, COSV99557592; called by muse, mutect2
- DOCK9 | c.1500T>C p.S500= (on ENST00000376460 / NM_001366676.2; = p.S501= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV59638173; called by muse, mutect2, varscan2
- ENO3 | c.1011C>T p.C337= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV52778637; called by muse, mutect2, varscan2
- FAM171A1 | c.708G>A p.L236= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1342161205, COSV65318402; called by muse, mutect2, varscan2
- FAT1 | c.10263C>T p.V3421= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV71675331; called by muse, mutect2, varscan2
- ITIH6 | c.867C>T p.D289= | Silent (SNP) | VAF 25/115 reads (22%) | catalogued as rs201639570, COSV99512800; called by muse, mutect2, varscan2
- KIF21B | c.3882G>A p.R1294= (on ENST00000422435 / NM_001252100.2; = p.R1281= on NM_017596.4) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs267598288, COSV100143528; called by muse, mutect2, varscan2
- LPP | c.1056G>A p.K352= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV57106085; called by muse, mutect2, varscan2
- LRRC36 | c.1455G>T p.L485= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV52081283; called by muse, mutect2, varscan2
- MARCHF2 | c.318C>T p.C106= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs201229492, COSV99294647; called by muse, mutect2, varscan2
- NKAPL | c.78C>T p.S26= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs1396219737, COSV59198780; called by muse, mutect2, varscan2
- PHF1 | c.1008T>C p.P336= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV65703239; called by muse, mutect2
- PRICKLE1 | c.1608G>A p.S536= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs144062651; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR38 | c.327G>A p.E109= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV62161291; called by muse, mutect2, varscan2
- ZNF521 | c.276T>C p.S92= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1364025891, COSV100831383; called by muse, mutect2, varscan2
